CCDI case PBCMSE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ffb10fe8-f4f7-4f68-b96d-caf10a9edb0c

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pineoblastoma: ICD-O-3 morphology code: 9362/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.2 years (4,091 days).

Biospecimens (3 samples)
- Sample 0DVCEY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVCF8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVCFY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
